Surgical pathology report (de-identified scan), TCGA case TCGA-76-6191, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6191-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]
Patient: [REDACTED]

ADDED

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-76-6191

FINAL DIAGNOSIS:

1. Left temporal lobe brain tumor: GLIOBLASTOMA, WHO GRADE iv. SEE MICROSCOPIC DESCRIPTION.
2. Left temporal lobe brain tumor: GLIOBLASTOMA, WHO GRADE iv.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Addendum

IMMUNOHISTOCHEMICAL STAINS

GFAP: POSITIVE STAINING OF TUMOR CELLS.

KI67: AREAS OF THE TUMOR SHOW ON SLIDE 2A POSITIVE NUCLEAR STAINING OF GREATER THAN 30% OF TUMOR CELL NUCLEI.

P53: POSITIVE STAINING OF ONLY A VERY FEW CELLS WITHIN THE TUMOR SPECIMEN (SLIDE 2A).

[REDACTED] Date Reported:

[REDACTED] Report Electronically Signed

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. The features of Glioblastoma including areas of pseudopalisading necrosis are best seen on the actual frozen tissue sections.

Frozen Section Diagnosis:

[page 2 of 3]
[REDACTED]
1. Left temporal lobe brain tumor: Glioblastoma. Frozen section
diagnosis by [REDACTED]

Clinical History and Diagnosis:

Left temporal lobe brain tumor

Source of Specimen:

- 1: Left temporal lobe brain tumor
- 2: Left temporal lobe brain tumor

Gross Description:

- [REDACTED]
1. Left temporal lobe brain tumor: Received fresh for frozen are multiple fragments of tan-red soft tissue measuring 0.9 x 0.7 x 0.2 cm in aggregate dimension. Touch preps are prepared and approximately 50% of the specimen is submitted for frozen sectioning one cassette. The remainder is submitted for permanents in one additional cassette
2. Left temporal lobe brain tumor: Received in formalin in a specimen container labeled with the patient's name and "#2 left temporal lobe brain tumor" are 2 fragments of tan-white soft tissue measuring 1.9 x 0.6 x 0.3 cm in aggregate. The specimen is entirely submitted in one cassette.

Histology Laboratory
H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

[page 3 of 3]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED] Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file f5dd640a-14e1-421d-add9-b0da6c061b35 (TCGA-76-6191.D91AA8CA-FE4B-4F2E-89A7-C56D6FE176E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).